Gene-level copy-number profile of tumor specimen TCGA-KB-A6F5-01A from TCGA case TCGA-KB-A6F5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.6 years (26,881 days).
Specimen TCGA-KB-A6F5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3a4505f0-57c6-4c8a-b79f-f00d77fa8e84.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KB-A6F5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/453b9cce-cdb7-4c64-b36d-6c5fa9a20415

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,321; copy number 2: 16,034; copy number 3: 21,818; copy number 4: 17,064; copy number 5: 1,378; copy number 6: 1,291; copy number 7: 479; copy number 8: 11; copy number 9: 25; copy number 10: 295; copy number 13: 96.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KB-A6F5-01A-12D-A33S-01): tumor purity 0.41, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 906 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:57,841,721–58,118,070, 3 genes, copy number 8: AC104790.1, SRIP1, AC096725.1.
- chr7:70,972–16,888,885, 284 genes, copy number 7 (broad region; genes not listed).
- chr7:16,938,225–16,938,557, 1 gene, copy number 7: AC098592.1.
- chr7:141,907,813–142,106,747, 1 gene, copy number 7 (within-gene range 4–7): MGAM.
- chr7:141,972,631–142,222,324, 2 genes, copy number 7: TAS2R38, MGAM2.
- chr11:2,129,112–2,173,138, 9 genes, copy number 9: IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686.
- chr12:52,821,408–53,042,215, 8 genes, copy number 8 (within-gene range 3–8): KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2.
- chr13:43,823,909–44,397,714, 16 genes, copy number 9 (within-gene range 4–9): CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2.
- chr13:73,036,401–73,661,891, 10 genes, copy number 10–13 (within-gene range 5–13): PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr19:27,638,483–38,773,492, 381 genes, copy number 10–13 (broad region; genes not listed).
- chr20:15,280,764–24,318,086, 191 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
